Somatic mutation profile of tumor specimen TCGA-2G-AAHP-01A (aliquot TCGA-2G-AAHP-01A-12D-A42Y-10) from TCGA case TCGA-2G-AAHP, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 31.9 years (11,649 days).
Specimen TCGA-2G-AAHP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9812ebfd-f6fc-421b-b041-2a6c0267e917.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAHP-10A (Blood Derived Normal), aliquot TCGA-2G-AAHP-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49af3bb8-4387-466b-b0fd-379cb64b925e

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 9, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COG5 | c.1694A>G p.H565R (on ENST00000347053 / NM_001379512.1; = p.H586R on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99772108; called by muse, mutect2, varscan2
- HDLBP | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1200637799; called by muse, mutect2
- KCNA4 | c.1879_1881del p.E627del | In Frame Del (DEL) | VAF 34/74 reads (46%) | catalogued as rs760802590; called by pindel, varscan2
- ANKRD50 | c.1909G>A p.V637M | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- CACNA1E | c.6238G>A p.G2080S (on ENST00000367573 / NM_001205293.3; = p.G2037S on NM_000721.4) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DNMT1 | c.2984G>A p.R995Q | Missense Mutation (SNP) | VAF 70/311 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- E2F7 | c.272T>G p.I91S | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PLXND1 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF15 | c.1220T>C p.L407P | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTGR1 | c.119A>C p.E40A | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
